Somatic mutation profile of tumor specimen TARGET-20-PATEMV-09A (aliquot TARGET-20-PATEMV-09A-01D) from TARGET case TARGET-20-PATEMV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,633 days).
Specimen TARGET-20-PATEMV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c3f764c-2a53-4043-8a73-e253a139c3d1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATEMV-14A (Bone Marrow Normal), aliquot TARGET-20-PATEMV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d4e244-bf96-4797-9b74-efee70bd2de7

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 64/161 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.2220_2221insGACCCCG p.R741Dfs*17 | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | called by mutect2, pindel
